Surgical pathology report (de-identified scan), TCGA case TCGA-F5-6810, project TCGA-READ (Rectum Adenocarcinoma), tissue source site Asterand, specimen TCGA-F5-6810-01A (Primary Tumor).

[page 1 of 2]
			Formatted Path Report
			LARGE INTESTINE TISSUE CHECKLIST
			Specimen type: Excision of tumor
			Specimen size: Not specified
			Tumor site: Rectum
			Tumor size: 7 x 6 x 1.5 cm
			Tumor features: None specified
			Histologic type: Adenocarcinoma
			Histologic grade: Moderately differentiated
			Tumor extent: Perirectal tissues
			Lymph nodes: 0/3 positive for metastasis (Regional 0/3)
			Margins: Not specified
			Evidence of neo-adjuvant treatment: Not specified
			Additional pathologic findings: Not specified
			Comments: Accompanied by tubular adenoma

[page 2 of 2]
Date of Procurement

Source: NCI Genomic Data Commons file 79387e4e-9cc5-4b63-9b02-428cdd708b98 (TCGA-F5-6810.F1EFF0B9-E0C6-409E-BC3F-D2F5BFB57CEB.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).